Surgical pathology report (de-identified scan), TCGA case TCGA-59-A5PD, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Roswell Park, specimen TCGA-59-A5PD-01A (Primary Tumor).

[page 1 of 5]
ICD-0-3
Cystadenocarcinoma, serous
8441/3
Site: R Ovary C56.9
JW 2/1/13

SPECIMEN(S): A. RIGHT TUBE AND OVARY
B. UTERUS, CERVIX, LEFT TUBE AND OVARY
C. APPENDIX
D. OMENTUM
E. LEFT PARA COLIC
F. RIGHT PARA COLIC
G. BLADDER PERINEUM
H. POSTERIOR CUL DE SAC
I. RIGHT PELVIC LYMPH NODES
J. LEFT PELVIC LYMPH NODES
K. PARA AORTIC LYMPH NODES

CLINICAL HISTORY:

African American female with postmenopausal bleeding, complex right adnexal mass and elevated CA 125 level 339.1.

PRE-OPERATIVE DIAGNOSIS:

Right adnexal mass, elevated CA 125

FROZEN SECTION INTRAOPERATIVE REPORT:

FSA/TPA: Ovary and fallopian tube, right, RSO: High grade malignant neoplasm, defer to permanent

Part B, Uterus, cervix, left tube and ovary, TAH-LSO: Gross examination: No tumor seen, gross examination only

GROSS DESCRIPTION:

A. RIGHT TUBE AND OVARY

Received fresh labeled with the patient's identification and designated "right tube and ovary" is an intact ovarian mass, 10 x 6 x 5 cm, weighing 161 g. The serosal surface is smooth and tan, inked black. The attached, dilated fallopian tube, 11 x 2.2 cm, demonstrates a smooth pink serosal surface. The mass is sectioned to show a lobulated, pale tan/yellow granular cut surface with focal areas of hemorrhage and necrosis. Gross photographs are taken. A portion of the specimen is submitted for tissue procurement.

Representatively submitted:

FSA1-FSA2: Frozen section, representative sections

A3: Representative sections fallopian tube and adjacent ovarian mass

A4: Additional sections proximal fallopian tube

A5-A12: Representative sections, ovarian mass

B. UTERUS, CERVIX, LEFT TUBE AND OVARY

Received fresh labeled with the patient's identification designated "uterus, cervix, left tube and ovary" is a resected hysterectomy specimen with attached ovary and fallopian tube weighing 103 g. The uterus and attached cervix, 9.5 x 5 x 2.5 cm, demonstrates a

[page 2 of 5]
smooth tan serosal surface. The anterior serosa inked blue, posterior-black. The ectocervix demonstrates a smooth white mucosal surface. The specimen is bivalved to show a pink-tan finely granular endometrial cavity. Sectioning through the endomyometrium shows multiple firm white nodules ranging from 0.3 x 0.3 x 0.2 up to 0.7 x 0.6 x 0.5 cm. The average endometrial thickness is 0.3 cm, myometrium-1.8 cm. The left ovary, 1.8 x 1.6 x 0.7 cm, demonstrates a smooth tan cerebriform serosal surface. In sectioning shows firm tan fibrous parenchyma. The fallopian tube with fimbriated end, 6.2 x 0.5 CM, shows a smooth pink serosal surface. Gross photographs are taken. The specimen is representatively submitted:

B1: Anterior cervix

B2: Posterior cervix

B3-B4: Full thickness sections, anterior uterine wall

B5: Full thickness section, fundus, white nodule (largest)

B6-B7: Full thickness sections posterior uterine wall

B8: Representative section (s) ovary, fallopian tube

C. APPENDIX

Received in formalin labeled with the patient's identification and 'appendix' is an intact C-shaped appendix 7cm in length and 0.8cm in diameter with attached unremarkable tan yellow mesoappendix 4.6 x 2.3cm. The serosal surface is tan pink and smooth. The proximal margin is shaved. The distal tip is longitudinally sectioned to reveal red-brown fecal material. The wall thickness is up to 0.3cm. No lesions are grossly identified.

Representatively submitted:

C1: proximal margin and cross section

C2: distal tip

D. OMENTUM

Received in formalin labeled with the patient's identification and 'omentum' is a tan yellow segment of omentum 51 x 21 x 2cm. The specimen is serially sectioned. No lesions or nodules are grossly identified. Representatively submitted in D1-D2.

E. LEFT PARA COLIC

Received in formalin labeled with the patient's identification and 'left para colic' is a tan pink soft tissue fragment 0.9 x 0.6 x 0.3cm. Toto E1.

F. RIGHT PARA COLIC

Received in formalin labeled with the patient's identification and 'right para colic' is a tan pink mucosal soft tissue fragment 1.3 x 0.6 x 0.2cm. The specimen is bisected. Toto F1.

G. BLADDER PERINEUM

Received in formalin labeled with the patient's identification and 'bladder perineum' is a tan pink mucosal soft tissue fragment 0.6 x 0.4 x 0.2cm. Toto G1.

H. POSTERIOR CUL DE SAC

Received in formalin labeled with the patient's identification and 'posterior cul de sac' is a tan yellow soft tissue fragment 0.5 x 0.4 x 0.3cm. Toto H1.

I. RIGHT PELVIC LYMPH NODES

Received in formalin labeled with the patient's identification and 'right pelvic lymph nodes' are multiple tan pink soft tissue fragments aggregating to 5.6 x 2.9 x 1.5cm.

Dissection reveals seven possible lymph nodes ranging from 0.7 x 0.6 x 0.5cm to 0.3 x 0.3 x 0.3cm.

[page 3 of 5]
I1: three lymph nodes

I2: four lymph nodes

J. LEFT PELVIC LYMPH NODES

Received in formalin labeled with the patient's identification and 'left pelvic lymph nodes' are multiple tan pink soft tissue fragments aggregating to 3.9 x 2.7 x 1.5cm. Dissection reveals a two lymph nodes ranging from 3.2 x 1.6 x 0.9cm to 0.3 x 0.2 x 0.2cm.

J1:one lymph nodes

J2-J3: one lymph node

K. PARA AORTIC LYMPH NODES

Received in formalin labeled with the patient's identification and 'para aortic lymph nodes' is a tan yellow soft tissue fragment 2.3 x 1.4 x 1cm. The specimen is serially sectioned. No lymph node is grossly identified. Toto K1.

DIAGNOSIS:

A. RIGHT TUBE AND OVARY:

- HIGH GRADE SEROUS CARCINOMA.
- THE TUMOR MEASURES 10.0 X 6.0 X 5.0 CM.
- (MICROSCOPIC BREAK IN THE CAPSULE).
- LYMPHOVASCULAR INVASION IS PRESENT.
- FALLOPIAN TUBE WITH PARATUBAL CYSTS.
- SEE SYNOPTIC REPORT.

B. UTERUS, CERVIX, LEFT TUBE AND OVARY:

- ATROPHIC ENDOMETRIUM.
- ADENOMYOSIS.
- CERVIX WITHOUT PATHOLOGIC ABNORMALITY.

- LEFT OVARY WITH SMALL HIGH GRADE SEROUS ADENOCARCINOMA.
- SEE SYNOPTIC REPORT.

- LEFT FALLOPIAN TUBE WITHOUT PATHOLOGIC ABNORMALITY.

C. APPENDIX:

- APPENDIX SHOWING MARKEDLY REACTIVE LYMPHOID FOLLICLES.

D. OMENTUM:

- UNREMARKABLE FIBROADIPOSE TISSUE.
- NEGATIVE FOR MALIGNANCY.

E. LEFT PARA COLIC:

- UNREMARKABLE FIBROADIPOSE TISSUE.
- NEGATIVE FOR MALIGNANCY.

[page 4 of 5]
- F. RIGHT PARA COLIC:
- UNREMARKABLE FIBROADIPOSE TISSUE.
- NEGATIVE FOR MALIGNANCY.
- G. BLADDER PERINEUM:
- UNREMARKABLE FIBROCONNECTIVE TISSUE.
- NEGATIVE FOR MALIGNANCY.
- H. POSTERIOR CUL DE SAC:
- UNREMARKABLE FIBROADIPOSE TISSUE.
- NEGATIVE FOR MALIGNANCY.
- I. RIGHT PELVIC LYMPH NODES:
- SEVEN LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/7).
- J. LEFT PELVIC LYMPH NODES:
- TWO LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/2).
- K. PARA AORTIC LYMPH NODES:
- BENIGN FIBROADIPOSE TISSUE WITH VESSELS AND NERVE FIBERS.
- NO LYMPHOID TISSUE IS SEEN (0/0).

SYNOPTIC REPORT - OVARY

Specimens Involved

Specimens: A: RIGHT TUBE AND OVARY

Specimen Type: TAH/BSO

Primary tumor site and size: Right Side
Involved
Largest Dimension: 10cm
Additional Dimensions: 6cm x 5cm
Left Side
Involved
Largest Dimension: 0.2cm

Specimen integrity: Intact

Gross surface involvement: No

Cut surface: Solid

Gross necrosis: Yes

WHO CLASSIFICATION

Serous tumors

Adenocarcinoma 8441/3

TUMOR GRADING

Architecture pattern: 3 (Solid)

Cytologic atypia: 3

Mitotic grade: 3 (>25)

Silverberg grading system: 3 (Score 8 or 9)

Summary of organs/tissues microscopically involved: Both ovaries

[page 5 of 5]
Venous/lymphatic invasion: Present

Implants: N/A

Lymph node dissection: Yes Right pelvic 0 / 7 Left pelvic 0 / 2 Paraaortic 0 / 0

Peritoneal cytology if tumor limited to ovary: Negative

Cytology case #:

Additional pathologic findings: None

NY ESO-1: Pending

Pathologic staging (pTNM): pT 1c(IC) N 0 M x

Pathological staging is based on the AJCC Cancer Staging Manual, 7th Edition

pMX: Cannot be assessed

Comment(s): Microscopic break in the right ovarian capsule. Tumor size in the left ovary is measured on slide.

ADDENDUM:

NYESO-1 by IHC: NEGATIVE (with appropriate positive control).

Case discussed with (

Source: NCI Genomic Data Commons file 15d0a696-f4a6-48f0-9a34-98c6f045eca1 (TCGA-59-A5PD.9A3CB382-654F-4DFD-BF41-7615710D2825.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).